Somatic mutation profile of tumor specimen TARGET-10-PAPHJF-09A (aliquot TARGET-10-PAPHJF-09A-01D) from TARGET case TARGET-10-PAPHJF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,511 days).
Specimen TARGET-10-PAPHJF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b774307-21cf-4c1f-abc2-94ff0017a76f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHJF-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHJF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2a5a144-ed67-499b-8316-1c1fe0b8e1c3

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Silent 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.5078C>T p.T1693M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs567116417, COSV55892252; called by muse, mutect2, varscan2
- ARSJ | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756542116, COSV59537244; called by muse, mutect2, varscan2
- ATM | c.3742T>C p.Y1248H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53735159; called by muse, mutect2, varscan2
- PRR23C | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs1212399708; called by muse, mutect2, varscan2
- SETD1B | c.5392C>T p.R1798C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57349029; called by muse, mutect2, varscan2
- TENT5D | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs137952753, COSV100382518; called by muse, mutect2, varscan2
- TFE3 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59946315; called by muse, mutect2, varscan2
- PKD1L3 | c.2198T>C p.V733A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PKHD1 | c.11084C>G p.T3695S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TRAJ57 | c.1_3delinsGG p.T2Lfs*16 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by pindel, varscan2*
- C10orf90 | c.219G>A p.P73= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs373665713, COSV52950802; called by muse, mutect2, varscan2
- ELMOD1 | c.225C>T p.D75= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs201524635; called by muse, mutect2, varscan2
- CCM2 | c.31-10563A>C | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- LRP1 | c.842-4350C>T | Intron (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- METAP1D | c.348+26G>A | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as rs368239638; called by muse, mutect2, varscan2
- MYT1L | c.3415-67A>G | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- ZNF157 | c.-58A>T | 5'UTR (SNP) | VAF 6/57 reads (11%) | called by mutect2, varscan2
